Gene-level copy-number profile of tumor specimen TCGA-55-7573-01A from TCGA case TCGA-55-7573, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.0 years (26,302 days).
Specimen TCGA-55-7573-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e3a1f5eb-1496-4f72-bd1c-a865846aec9d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-7573-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/01b7bd2b-0778-4872-95f1-ba2f3e3d417b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 12,545; copy number 3: 27,122; copy number 4: 4,866; copy number 5: 6,384; copy number 6: 8,381; copy number 7: 284; copy number 8: 238.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-7573-01A-11D-2035-01): tumor purity 0.33, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 522 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:154,688,296–157,327,713, 28 genes, copy number 7: AC061961.1, KCNJ3, CBX3P6, AC092625.1, RNU6-1001P, MTCO1P45, MTND2P20, ATP5F1AP2, MTND4P28, MTND5P30, MTND6P9, MTCYBP9, RNU6-546P, AC073225.1, LINC01876, HEBP2P1, AC074099.1, NR4A2, GPD2, LINC01958, RPLP0P7, AC096589.2, AC096589.1, AC108057.1, CDK7P1, GALNT5, RN7SKP281, ERMN.
- chr4:35,948,221–39,458,931, 54 genes, copy number 8 (within-gene range 6–8): ARAP2, AC098827.1, AC104078.1, DTHD1, AC104078.2, MIR1255B1, LINC02505, AC125336.1, AC093746.1, LINC02616, AL136537.1, MIR4801, NWD2, C4orf19, AC022463.1, AC027607.1, RELL1, Y_RNA, AC108022.1, PGM2, AC021106.2, AC021106.1, TBC1D1, PTTG2, PSME2P4, MRPS33P2, AC098680.2, AC098680.1, LINC02513, AC024023.1, LINC01258, LINC01259, LINC02278, KLF3-AS1, AC021860.1, KLF3, RNA5SP158, TLR10, TLR1, TLR6, FAM114A1, MIR574, TMEM156, KLHL5, AC079921.1, AC079921.2, WDR19, RFC1, RNU6-32P, RNU6-887P, KLB, MIR5591, Y_RNA, RPL9.
- chr5:18,965,861–23,689,386, 34 genes, copy number 8 (within-gene range 6–8): AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1.
- chr5:169,012,148–179,610,012, 259 genes, copy number 7–8 (broad region; genes not listed).
- chr7:19,353,531–22,357,154, 34 genes, copy number 7: AC007091.1, POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1, EEF1A1P27, AC002486.2, ABCB5, AC002486.1, SP8, RPL23P8, LINC01162, RPS26P30, AC080068.1, RN7SL542P, ASS1P11, RNU1-15P, AC005094.1, SP4, MIR1183, DNAH11, CDCA7L, RAPGEF5, RNA5SP227.
- chr7:22,510,616–22,511,999, 1 gene, copy number 7: EEF1A1P6.
- chr17:19,061,912–20,771,427, 112 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
